Somatic mutation profile of tumor specimen 0DQ2NG from CCDI case PBCEKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,561 days).
Specimen 0DQ2NG: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1a7d604-b114-4c50-8bc3-0b5d9ee387fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2OZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb2f4cf-e906-4015-a46d-c00a11ebb299

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Missense Mutation 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 33/257 reads (13%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- CHCHD2 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 21/551 reads (4%) | catalogued as rs1174843615; called by muse, mutect2
- COQ6 | c.1118dup p.L374Afs*40 | Frame Shift Ins (INS) | VAF 146/458 reads (32%) | called by mutect2, pindel, varscan2
- SFXN5 | c.788T>A p.I263N | Missense Mutation (SNP) | VAF 46/876 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- APOA5 | c.390G>A p.K130= | Silent (SNP) | VAF 13/480 reads (3%) | called by muse, mutect2
- MMP12 | c.852C>T p.P284= | Silent (SNP) | VAF 24/687 reads (3%) | catalogued as rs781821688; called by muse, mutect2
- AP3B1 | c.2993-23G>A | Intron (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- DPYSL5 | c.*72G>A | 3'UTR (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
